CCDI case PBBNNM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/0bf3e199-26fa-4298-95fc-5bb1b78bf1c9

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Spindle cell carcinoma, NOS: ICD-O-3 morphology code: 8032/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 0.2 years (72 days).

Biospecimens (3 samples)
- Sample 0DE3GR: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DE3GW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DE3H6: Tissue type: Tumor; Specimen type: Solid Tissue.
